TCGA case TCGA-AZ-6598 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a8b4284d-cbbb-43e3-897b-d04af4bfba74

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 77 years; Vital status: Dead; Days to death: 1,503 days (4.1 years).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 77.2 years (28,182 days); Year of diagnosis: 2000; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,503 days (4.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 24; Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,503 days (4.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 7.5 ng/mL.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AZ-6598-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.9; Intermediate dimension: 1.6; Shortest dimension: 0.6.
  Slide TCGA-AZ-6598-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-AZ-6598-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-AZ-6598-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AZ-6598-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.2; Intermediate dimension: 1.1; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: Yes; CEA level pretreatment: 7.5; Lymphovascular invasion indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,503 days; disease-specific survival: no event (censored), 1,503 days; disease-free interval: no event (censored), 1,503 days; progression-free interval: no event (censored), 1,503 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AZ-6598-01A-11D-1770-01): tumor purity 0.86, ploidy 2.28, whole-genome doublings 0.
